Surgical pathology report (de-identified scan), TCGA case TCGA-WE-AAA3, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-AAA3-06A (Metastatic).

ADDRESS FOR REPORT:
Report to Cancer Registry

HISTOPATHOLOGY REPORT

*ADDITIONAL REPORT

LAB No:

CASE HISTORY:

Malignant melanoma left thigh. Palpable lymphadenopathy left groin.
Previous IL1. (specimen tissue sampled)

MACROSCOPIC:

Ellipse of unremarkable skin (18 x 4 cm) covering adipose tissue 20 x 9 x 1.4 cm.
Slicing shows several lymph nodes the largest measuring 2.8 cm. Blocks A, B, C, D, E
and F = one node each. G, H = a single node in both cassettes. I = single node. J, K =
one node.

MICROSCOPY:

Nine lymph nodes, two of which contain metastatic melanoma up to 28 mm diameter
(macroscopic measurement). Extracapsular spread is not seen but melanoma is
present within extranodal lymphatics.

DIAGNOSIS:

LEFT GROIN DISSECTION: METASTATIC MELANOMA (2/9).

REPORTED BY:

Dr Doctor, Histopathology
Dr Consultant Histopathologist

REPORT DATE:

Additional report

The tumour is BRAF negative

Dr Consultant Histopathologist

ICD O3

Melanoma NOS 8720/3
Site Lymph node, groin
C77.4

JW 4/28/14

Source: NCI Genomic Data Commons file 3d43651f-be11-4897-a34b-37f3207f7f2a (TCGA-WE-AAA3.EF9CAD09-A258-420F-87F0-C3CF4ED1E4EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).